Somatic mutation profile of tumor specimen TCGA-DK-AA6M-01A (aliquot TCGA-DK-AA6M-01A-11D-A391-08) from TCGA case TCGA-DK-AA6M, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.5 years (23,574 days).
Specimen TCGA-DK-AA6M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa70a914-8df1-43cd-a1b0-e3824de754b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6M-10A (Blood Derived Normal), aliquot TCGA-DK-AA6M-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9801b5b8-bcfa-43a5-b212-765bd85bbf74

The open-access MAF lists 80 somatic variants for this specimen: 56 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 23, Nonsense Mutation 6, In Frame Del 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 36/61 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 59/502 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369487048, COSV57871248; called by muse, mutect2, varscan2
- ADGRL4 | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66061014, COSV66061808; called by muse, mutect2, varscan2
- AKR7A2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1162787787, COSV52516186; called by muse, mutect2, varscan2
- ATG2B | c.3973G>C p.D1325H | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV55889386, COSV55890434; called by muse, mutect2, varscan2
- AUTS2 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61402560; called by muse, mutect2, varscan2
- B4GALNT4 | c.2554G>A p.G852R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as rs1305826768, COSV100327543, COSV57323460; called by muse, mutect2, varscan2
- C1GALT1C1 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV58974219; called by muse, mutect2, varscan2
- CACNA1B | c.5297G>A p.C1766Y | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53127194; called by muse, mutect2, varscan2
- CACNA1F | c.5698G>A p.E1900K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100544292; called by muse, mutect2, varscan2
- CFAP299 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100811251; called by muse, mutect2, varscan2
- CLPTM1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs375387209; called by muse, mutect2, varscan2
- CNOT4 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV59652812; called by muse, mutect2, varscan2
- CTCF | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV50461476; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2, varscan2
- DACH2 | c.317T>A p.L106* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100912375; called by muse, mutect2, varscan2
- DGKK | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1557222798, COSV65707602; called by muse, mutect2, varscan2
- DIAPH2 | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448332434, COSV61270693; called by muse, mutect2, varscan2
- DICER1 | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as rs1170730150, COSV58620382; called by muse, mutect2, varscan2
- DMD | c.5824G>A p.A1942T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.475); catalogued as rs977284401, COSV63740787; called by muse, mutect2, varscan2
- EDDM3B | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141966055; called by muse, mutect2, varscan2
- EP300 | c.4589del p.E1530Gfs*11 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV54333139; called by mutect2, pindel, varscan2
- FAM180A | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1191481895, COSV100647204; called by muse, mutect2, varscan2
- FILIP1 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV52723943, COSV52730417; called by muse, mutect2, varscan2
- FMN2 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100142178; called by muse, mutect2
- FREM2 | c.1744C>T p.L582F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54838839; called by muse, mutect2, varscan2
- GABRA4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as rs138764484; called by muse, mutect2, varscan2
- GANC | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 22/176 reads (13%) | PolyPhen probably damaging (0.992); catalogued as COSV58809145; called by muse, mutect2, varscan2
- GMIP | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs373620612; called by muse, mutect2
- GPR132 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765720156, COSV61677952; called by muse, mutect2, varscan2
- HAS3 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54707121; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1179G>C p.K393N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52375703; called by muse, mutect2, varscan2
- IBTK | c.3368G>A p.R1123K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1425896468, COSV60393081; called by muse, varscan2
- KMT2D | c.14449G>A p.V4817M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56442388; called by muse, mutect2, varscan2
- LOXL2 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755780161, COSV66691556; called by muse, mutect2, varscan2
- LRP2 | c.13303G>A p.V4435I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751890334, COSV55554573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP2 | c.10361T>C p.I3454T | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55554584; called by muse, mutect2, varscan2
- MYH9 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV99337707; called by muse, mutect2, varscan2
- NF2 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs374494685, COSV100097113; called by muse, mutect2, varscan2
- NR3C2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1189474389, COSV60991214; called by muse, mutect2, varscan2
- OR6B3 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs746967614, COSV100096816; called by muse, mutect2, varscan2
- PABPC4 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV63293425; called by muse, mutect2, varscan2
- PHEX | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1222346086, COSV104432321, COSV65075768; called by muse, mutect2, varscan2
- POU4F2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs544750597, COSV55584502; called by muse, mutect2, varscan2
- RB1 | c.1360_1362del p.Y454del | In Frame Del (DEL) | VAF 13/22 reads (59%) | catalogued as COSV57308664; called by mutect2, pindel, varscan2
- SALL1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.089); catalogued as rs752432804, COSV51753014; called by muse, mutect2, varscan2
- SDHA | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.273); catalogued as rs575617625, COSV53766392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2D3C | c.671G>A p.R224H (on ENST00000314830 / NM_170600.3; = p.R67H on NM_005489.4) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs772668891, COSV59123471; called by muse, mutect2
- SLC46A1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100398010; called by muse, mutect2
- SLC5A6 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV60159574; called by muse, mutect2, varscan2
- SP110 | c.1840C>T p.Q614* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99282924; called by muse, mutect2, varscan2
- SPDYC | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV65865204; called by muse, mutect2, varscan2
- SPTA1 | c.2981G>T p.R994L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs746992826, COSV63751577, COSV63751790; called by muse, mutect2, varscan2
- TDRD9 | c.3048G>A p.M1016I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs760014806, COSV100174557; called by muse, varscan2
- TLR7 | c.2568G>A p.M856I | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV66124375; called by muse, mutect2, varscan2
- ZNF831 | c.2587G>A p.G863R | Missense Mutation (SNP) | VAF 132/161 reads (82%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs558775656, COSV64040185; called by muse, mutect2, varscan2
- CACNA1D | c.3825C>T p.L1275= (on ENST00000350061 / NM_001128840.3; = p.L1295= on NM_000720.4) | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV55447961; called by muse, mutect2, varscan2
- CCDC62 | c.1023C>T p.V341= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs781754110, COSV53433818; called by muse, mutect2, varscan2
- CDC123 | c.381C>T p.L127= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV55397831; called by muse, mutect2, varscan2
- CSF3 | c.408G>A p.L136= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV56640915; called by muse, mutect2, varscan2
- DNTTIP1 | c.837C>A p.A279= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV54754987; called by muse, mutect2, varscan2
- F3 | c.729C>A p.G243= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV61845033; called by muse, mutect2, varscan2
- GDF5 | c.156C>T p.P52= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs111902988, COSV100976705; called by muse, varscan2
- GOLGB1 | c.2955G>A p.K985= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV61466098; called by muse, mutect2, varscan2
- GPR62 | c.612G>A p.L204= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59054689; called by muse, mutect2
- H1-6 | c.573A>G p.K191= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as rs1027413053, COSV58090625; called by muse, mutect2, varscan2
- IGF2BP3 | c.1509T>C p.I503= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as COSV51685179; called by muse, mutect2, varscan2
- KLHL1 | c.417C>T p.H139= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV64766467, COSV64772963; called by muse, mutect2, varscan2
- KLHL17 | c.1875C>T p.L625= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs535496329, COSV58531949; called by muse, mutect2, varscan2
- LAYN | c.945C>T p.F315= (on ENST00000375615 / NM_001258390.1; = p.F307= on NM_178834.5) | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV65104860; called by muse, mutect2, varscan2
- LRRC7 | c.3312C>T p.I1104= (on ENST00000651989 / NM_001370785.2; = p.I1071= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs373995293, COSV99228797; called by muse, mutect2, varscan2
- NDUFA1 | c.126G>A p.G42= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as rs1169478795, COSV65097380; called by muse, mutect2, varscan2
- NPBWR1 | c.855C>T p.V285= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV58696253; called by muse, mutect2
- PCDHB13 | c.1620G>A p.A540= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV53394590, COSV53399179; called by muse, mutect2, varscan2
- PHF12 | c.729G>A p.R243= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV52019404; called by muse, mutect2, varscan2
- PTPN1 | c.366A>G p.A122= | Silent (SNP) | VAF 14/213 reads (7%) | catalogued as COSV65408129; called by muse, mutect2
- SEC31A | c.1983G>A p.K661= (on ENST00000355196 / NM_001318120.1; = p.K622= on NM_016211.4) | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV52345993; called by muse, mutect2, varscan2
- TRPA1 | c.1695G>A p.A565= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as rs148317110; called by muse, mutect2, varscan2
- ZNF510 | c.1509C>T p.L503= | Silent (SNP) | VAF 52/225 reads (23%) | catalogued as COSV56296832, COSV56297382; called by muse, mutect2, varscan2
- DERL3 | c.*2032C>T | 3'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as rs745936222, COSV51954897; called by muse, mutect2, varscan2
